Somatic mutation profile of tumor specimen C3L-04733-03 (aliquot CPT0246390005) from CPTAC case C3L-04733, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 78.4 years (28,623 days).
Specimen C3L-04733-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb8c717c-3fe4-4c74-bed3-29657818aee5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04733-31 (Blood Derived Normal), aliquot CPT0249680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43ca152a-ff1d-415c-a76b-7a7e21f6a8dd

The open-access MAF lists 1,988 somatic variants for this specimen: 1,224 protein-altering or splice-affecting, 692 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,126, Silent 692, Nonsense Mutation 60, Intron 47, Frame Shift Del 10, 3'UTR 9, Splice Region 9, Splice Site 7, 5'Flank 6, Translation Start Site 6, 5'UTR 5, Frame Shift Ins 4.

Variants (750 of 1,988; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MARCHF10 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 50/403 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs17853369, COSV60886636; called by muse, mutect2, varscan2
- ABCA1 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1461590067, COSV66063776; called by muse, mutect2
- ABCB1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.096); catalogued as COSV55963835; called by muse, mutect2
- ABCC3 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 51/436 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755649633, COSV53316754; called by muse, mutect2, varscan2
- ABCC9 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as COSV53987421; called by muse, mutect2
- ABL2 | c.1507C>T p.R503* (on ENST00000502732 / NM_007314.4; = p.R488* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 42/524 reads (8%) | catalogued as COSV61015911; called by muse, mutect2
- ABRAXAS2 | c.776G>A p.R259K | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs537159917, COSV53716687; called by muse, mutect2, varscan2
- AC004997.1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT deleterious, low confidence (0); catalogued as rs201164151; called by muse, mutect2, varscan2
- ACSM1 | c.120G>T p.W40C | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV54637523; called by muse, mutect2
- ADAM29 | c.1682A>T p.E561V | Missense Mutation (SNP) | VAF 52/417 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.497); catalogued as COSV63664957; called by muse, mutect2, varscan2
- ADAM7 | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs867202281, COSV51534566; called by muse, mutect2, varscan2
- ADAMTS16 | c.2801G>A p.G934E | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV99943602; called by muse, mutect2
- ADAMTSL1 | c.4117C>T p.P1373S | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.214); catalogued as COSV65879385; called by muse, mutect2, varscan2
- ADGRE5 | c.1606C>T p.L536F (on ENST00000242786 / NM_078481.4; = p.L443F on NM_001784.5) | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54390704; called by muse, mutect2
- ADGRG6 | c.3479C>T p.S1160F | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99749058; called by muse, mutect2, varscan2
- ADGRL2 | c.3443C>T p.S1148L (on ENST00000370717 / NM_001366005.1; = p.S1135L on NM_012302.4) | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs1488334868; called by muse, mutect2
- ADGRL3 | c.905G>A p.R302Q (on ENST00000506720 / NM_001322402.2; = p.R234Q on NM_015236.6) | Missense Mutation (SNP) | VAF 46/398 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1345765166, COSV72266433; called by muse, mutect2, varscan2
- ADGRV1 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 42/409 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV67978760; called by muse, mutect2
- ADGRV1 | c.8630G>A p.G2877E | Missense Mutation (SNP) | VAF 46/384 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV67979553; called by muse, mutect2, varscan2
- ALDH16A1 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs1343127616, COSV53192943; called by muse, mutect2
- ALKBH2 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 42/398 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768650700; called by muse, mutect2, varscan2
- ALPK2 | c.5099G>A p.G1700E | Missense Mutation (SNP) | VAF 37/380 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs780319635; called by muse, mutect2
- ANGPT1 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 135/415 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138754767, COSV52431155; called by muse, mutect2, varscan2
- ANGPTL7 | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 30/359 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as rs1384103777; called by muse, mutect2
- ANK3 | c.10679G>A p.R3560Q | Missense Mutation (SNP) | VAF 49/486 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as rs756241696, COSV55061219; ClinVar: uncertain significance; called by muse, mutect2
- ANKRD44 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 29/336 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.019); catalogued as rs1464487603; called by muse, mutect2
- ANXA7 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs867363009, COSV100873495; called by muse, mutect2, varscan2
- APOBEC3A | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 22/283 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.816); catalogued as rs755695458; called by muse, mutect2, varscan2
- ARHGEF5 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 38/664 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs761104506; called by muse, mutect2
- ARID2 | c.5110G>T p.E1704* | Nonsense Mutation (SNP) | VAF 30/328 reads (9%) | catalogued as COSV57601074; called by muse, mutect2
- ARSJ | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 43/372 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59539174; called by muse, mutect2, varscan2
- ART1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 49/429 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51702739; called by muse, mutect2, varscan2
- ASIC5 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 74/547 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs753653000, COSV72232528; called by muse, mutect2, varscan2
- ASPH | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 126/451 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV65245614; called by muse, mutect2, varscan2
- ASTN2 | c.1171G>A p.G391R (on ENST00000313400 / NM_001365069.1; = p.G340R on NM_014010.5) | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs368733408, COSV100527346; called by muse, mutect2, varscan2
- ATF7 | c.497C>T p.S166F (on ENST00000548446 / NM_001366555.2; = p.S155F on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/484 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100129642; called by muse, mutect2, varscan2
- ATP13A4 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.597); catalogued as COSV55071924; called by muse, mutect2, varscan2
- ATXN7L1 | c.2248C>T p.L750F | Missense Mutation (SNP) | VAF 62/678 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as rs1170050603, COSV66300972; called by muse, mutect2
- BAZ1A | c.2824C>T p.H942Y | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as rs866148207; called by muse, mutect2
- BCL9L | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 66/483 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1484233310; called by muse, mutect2, varscan2
- BICRA | c.2441C>T p.P814L | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs573210309; called by muse, mutect2
- BLMH | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55585880; called by muse, mutect2, varscan2
- BRAF | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.994); catalogued as rs1409723450; called by muse, mutect2, varscan2
- BSN | c.9509C>T p.P3170L | Missense Mutation (SNP) | VAF 57/569 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1559618905; called by muse, mutect2
- C10orf71 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 59/401 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs745969517; called by muse, mutect2, varscan2
- C10orf71 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 49/340 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60505727; called by muse, mutect2, varscan2
- C12orf40 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV61131200; called by muse, mutect2, varscan2
- C12orf40 | c.1610G>A p.G537D | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs1426679551; called by muse, mutect2, varscan2
- C1orf68 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 121/426 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1270441607; called by muse, mutect2, varscan2
- C2CD4C | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 57/500 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV59967075; called by muse, mutect2, varscan2
- C5AR1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.015); catalogued as rs1185079633, COSV61892151; called by muse, mutect2, varscan2
- C8A | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 46/412 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs778909267; called by muse, mutect2, varscan2
- CABP2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 57/443 reads (13%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.029); catalogued as rs762893343; called by muse, mutect2, varscan2
- CACNA1F | c.2888C>T p.S963L | Missense Mutation (SNP) | VAF 61/442 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375587802; called by muse, mutect2, varscan2
- CACNA1H | c.1901G>A p.G634E | Missense Mutation (SNP) | VAF 45/460 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as rs1279482046; called by muse, mutect2, varscan2
- CACNA2D3 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 16/347 reads (5%) | catalogued as rs1351986488, COSV55572961; called by muse, mutect2
- CACNG7 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776738193; called by muse, mutect2, varscan2
- CADPS2 | c.3034C>T p.L1012F | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57350186; called by muse, mutect2, varscan2
- CAMK2B | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.015); catalogued as rs753741079, COSV51660649; called by muse, mutect2
- CASP14 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT tolerated (0.46); PolyPhen probably damaging (1); catalogued as rs1568315995; called by muse, varscan2
- CATSPERD | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 42/327 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs745670557, COSV58465097; called by muse, mutect2, varscan2
- CBFA2T3 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as rs769175760, COSV51927995; called by muse, mutect2, varscan2
- CBL | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 42/394 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs371026706; called by muse, varscan2
- CCDC102A | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 48/588 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV50780005; called by muse, mutect2
- CCDC142 | c.2069C>T p.P690L (on ENST00000393965 / NM_001365575.2; = p.P683L on NM_032779.4) | Missense Mutation (SNP) | VAF 44/476 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs1459390108, COSV50688924; called by muse, mutect2
- CCR1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56121983; called by muse, mutect2, varscan2
- CD163 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 56/536 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373039092; called by muse, mutect2, varscan2
- CD163L1 | c.4339C>T p.P1447S | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.447); catalogued as COSV58013995; called by muse, varscan2
- CD200 | c.472G>A p.G158R (on ENST00000473539 / NM_001004196.3; = p.G133R on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); catalogued as COSV100238172; called by muse, mutect2
- CD300E | c.359C>A p.S120* | Nonsense Mutation (SNP) | VAF 29/363 reads (8%) | catalogued as COSV60789926; called by muse, mutect2
- CD300LF | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV56895981, COSV56896343; called by muse, mutect2
- CDH18 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 46/500 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV56924149, COSV56947682; called by muse, mutect2
- CENPM | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs138744954; called by muse, mutect2, varscan2
- CEP72 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 63/482 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs368269218; called by muse, mutect2, varscan2
- CER1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 38/356 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as rs779081119, COSV66603024; called by muse, mutect2
- CFAP46 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs915496495; called by muse, mutect2, varscan2
- CFHR4 | c.254G>A p.R85K (on ENST00000367416 / NM_001201551.2; = p.R86K on NM_001201550.3) | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.4); catalogued as rs1398455757, COSV52227611; called by muse, mutect2, varscan2
- CFHR4 | c.1292G>A p.G431E (on ENST00000367416 / NM_001201551.2; = p.G185E on NM_006684.5) | Missense Mutation (SNP) | VAF 129/463 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV52229902; called by muse, mutect2, varscan2
- CHL1 | c.3445C>T p.R1149W (on ENST00000397491 / NM_001253387.1; = p.R1165W on NM_006614.4) | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs144771821, COSV56588275; called by muse, varscan2
- CHRNA1 | c.52G>T p.V18F | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.197); catalogued as COSV53682806, COSV53684609; called by muse, mutect2, varscan2
- CHRNA7 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 45/1074 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as rs1321703394; called by muse, mutect2
- CLCA2 | c.2531C>T p.S844F | Missense Mutation (SNP) | VAF 46/482 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65288670; called by muse, mutect2
- CLEC12B | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 34/295 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as rs771673041; called by muse, mutect2, varscan2
- CLEC4C | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 23/338 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV100665439; called by muse, mutect2
- CLEC4E | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV55227370; called by muse, mutect2, varscan2
- CMYA5 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 38/453 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV101484201, COSV71409184, COSV71409886; called by muse, mutect2
- CMYA5 | c.4570G>A p.E1524K | Missense Mutation (SNP) | VAF 44/476 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as rs1217621222, COSV71409062, COSV71410497; called by muse, mutect2
- CNTN5 | c.2155G>A p.V719I | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV54290214; called by muse, mutect2
- COL14A1 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 36/439 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.438); catalogued as rs867973354, COSV52858729; called by muse, mutect2
- COL1A2 | c.455G>C p.R152P | Missense Mutation (SNP) | VAF 37/370 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV51952925; called by muse, mutect2
- COL20A1 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 67/722 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs866090610; called by muse, mutect2
- COL22A1 | c.2611G>A p.G871R | Missense Mutation (SNP) | VAF 128/458 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57322681; called by muse, mutect2, varscan2
- COL2A1 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs370138748; called by muse, mutect2, varscan2
- COL4A3 | c.2944G>C p.G982R | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59258093; called by muse, mutect2, varscan2
- COL4A5 | c.2450G>A p.G817E | Missense Mutation (SNP) | VAF 48/441 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60362103, COSV60364461; called by muse, mutect2, varscan2
- COL6A5 | c.4289G>A p.R1430Q | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as rs762054573, COSV55195014; called by muse, mutect2, varscan2
- COL9A1 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.939); catalogued as rs376107070; called by muse, mutect2, varscan2
- CORO1B | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 74/545 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs772528176; called by muse, mutect2, varscan2
- CPA6 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 151/463 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52722193; called by muse, mutect2, varscan2
- CPAMD8 | c.2881G>A p.D961N (on ENST00000651564; = p.D914N on NM_015692.5) | Missense Mutation (SNP) | VAF 47/370 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773820824, COSV71596737; called by muse, mutect2, varscan2
- CPNE2 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as rs770696614; called by muse, mutect2
- CPNE3 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 173/565 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs778618079; called by muse, mutect2, varscan2
- CPNE7 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs750254845; called by muse, mutect2
- CRACD | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 65/609 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV51716110; called by muse, mutect2, varscan2
- CRX | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 53/509 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs779129827; called by muse, mutect2, varscan2
- CSMD1 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 57/266 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs762477333, COSV68167822; called by muse, mutect2, varscan2
- CSMD1 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68219107; called by muse, mutect2, varscan2
- CSMD2 | c.2705G>A p.G902E | Missense Mutation (SNP) | VAF 53/448 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV53891835; called by muse, mutect2, varscan2
- CSMD3 | c.9898G>A p.G3300R (on ENST00000297405 / NM_001363185.1; = p.G3131R on NM_052900.3) | Missense Mutation (SNP) | VAF 117/420 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52335055; called by muse, mutect2, varscan2
- CSMD3 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 108/348 reads (31%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); catalogued as rs763316092, COSV52149077; called by muse, mutect2, varscan2
- CTAGE1 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 41/376 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.248); catalogued as rs1278715469; called by muse, mutect2, varscan2
- CTAGE1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 44/315 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101194634, COSV101194635; called by muse, mutect2, varscan2
- CTRC | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 42/500 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.887); catalogued as COSV65621484; called by muse, mutect2
- CTTNBP2 | c.4415C>T p.P1472L | Missense Mutation (SNP) | VAF 27/362 reads (7%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.548); catalogued as rs1323447590; called by muse, mutect2
- CUBN | c.8780C>T p.P2927L | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as rs771967930; called by muse, mutect2, varscan2
- CWC22 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 22/327 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99843910; called by muse, mutect2
- CYP21A2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 85/513 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.076); catalogued as COSV100925831, COSV100926202; called by muse, mutect2, varscan2
- CYP2C19 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 34/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1232142122, COSV64906940; called by muse, mutect2
- CYP3A4 | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV60502034; called by muse, mutect2, varscan2
- DCC | c.4054C>T p.P1352S | Missense Mutation (SNP) | VAF 35/304 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV71433494; called by muse, mutect2, varscan2
- DCHS1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 48/444 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs767229397; called by muse, mutect2, varscan2
- DECR1 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 161/515 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867052303, COSV55166675; called by muse, mutect2, varscan2
- DEFB105A | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 49/509 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV58294716; called by muse, mutect2
- DENND1B | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV52462055; called by muse, mutect2, varscan2
- DEUP1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 27/318 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV53212331; called by muse, mutect2
- DGKB | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV51802497; called by muse, mutect2, varscan2
- DIP2A | c.4092C>T p.I1364= | Splice Region (SNP) | VAF 31/333 reads (9%) | catalogued as COSV100595578; called by muse, mutect2
- DLG2 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV54678972; called by muse, mutect2, varscan2
- DLK2 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV55091112; called by muse, mutect2, varscan2
- DMD | c.7054G>A p.E2352K | Missense Mutation (SNP) | VAF 38/434 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as CM022955; called by muse, mutect2
- DMD | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 43/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057515876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH11 | c.5500C>T p.R1834C | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs180897552, CM140771, COSV60944662; ClinVar: uncertain significance; called by muse, mutect2
- DNAH2 | c.5230C>T p.R1744W | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765770535, COSV66720342; called by muse, mutect2
- DNAH5 | c.4896del p.W1632* | Frame Shift Del (DEL) | VAF 39/359 reads (11%) | catalogued as COSV54214880; called by pindel, varscan2
- DNAH5 | c.3634G>A p.A1212T | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV99451553; called by muse, mutect2, varscan2
- DNAH9 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs781679184, COSV52380087; called by muse, mutect2, varscan2
- DNAH9 | c.7084C>T p.P2362S | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.725); catalogued as COSV52335028; called by muse, mutect2, varscan2
- DNAI1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 39/373 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs762091795, COSV54282766; called by muse, mutect2, varscan2
- DNAI1 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV54285683; called by muse, mutect2
- DNM1 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 59/559 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1048565011; called by muse, mutect2, varscan2
- DOCK2 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 48/436 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.756); catalogued as rs867401091; called by muse, mutect2, varscan2
- DPEP3 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 53/413 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as rs1329114209; called by muse, mutect2, varscan2
- DSCAM | c.5687G>A p.G1896D | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.212); catalogued as rs1386426731; called by muse, mutect2, varscan2
- DSEL | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 74/474 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs963693612; called by muse, mutect2, varscan2
- DSG4 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV57397624; called by muse, mutect2, varscan2
- DYNC2H1 | c.2798C>T p.S933F | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs768430180; called by muse, mutect2, varscan2
- E2F2 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 59/475 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs756515833, COSV62276498, COSV62276725; called by muse, mutect2, varscan2
- E2F8 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372105528; called by muse, mutect2, varscan2
- EBF1 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 42/388 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1434366358, COSV58185070; called by muse, mutect2, varscan2
- EEF1G | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as rs11549641, COSV57744252; called by muse, mutect2, varscan2
- EFHC2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 42/397 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs776772685, COSV69553269; called by muse, mutect2, varscan2
- EGFL6 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 43/404 reads (11%) | catalogued as COSV63634485; called by muse, mutect2, varscan2
- EMC7 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs1348414728, COSV56628595; called by muse, mutect2, varscan2
- EML6 | c.4504C>T p.R1502* | Nonsense Mutation (SNP) | VAF 28/268 reads (10%) | catalogued as COSV62867070; called by muse, mutect2
- ENAM | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 32/303 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.317); catalogued as rs1335696374; called by muse, mutect2, varscan2
- ENOX1 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 54/540 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV54898225; called by muse, mutect2
- ENPP4 | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 39/364 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769628402, COSV58089042; called by muse, mutect2, varscan2
- ENPP5 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 60/501 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223906343; called by muse, mutect2, varscan2
- EPG5 | c.4270C>T p.P1424S | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56354251; called by muse, mutect2, varscan2
- ERBB4 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 29/396 reads (7%) | catalogued as COSV53574312; called by muse, mutect2
- ETNK2 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 40/628 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1295043621; called by muse, mutect2
- EXD1 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59256728; called by muse, mutect2
- EXOC5 | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as COSV61770074; called by muse, mutect2, varscan2
- EXOC7 | c.1080G>T p.E360D (on ENST00000335146 / NM_001145297.4; = p.E278D on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100135867; called by muse, mutect2, varscan2
- F11 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs281875270, CM950374, COSV53004471; ClinVar: not provided; called by muse, mutect2, varscan2
- FAM135B | c.3577C>T p.R1193W | Missense Mutation (SNP) | VAF 42/510 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1180715939, COSV52715961, COSV99417794; called by muse, mutect2
- FAM135B | c.1410G>A p.M470I | Missense Mutation (SNP) | VAF 138/469 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52705316; called by muse, mutect2, varscan2
- FAM193B | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 72/535 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.013); catalogued as rs754908606; called by muse, mutect2, varscan2
- FAT4 | c.14176C>T p.P4726S | Missense Mutation (SNP) | VAF 32/309 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV58682700; called by muse, mutect2, varscan2
- FBXO39 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV58621074; called by muse, mutect2, varscan2
- FBXO40 | c.1667G>A p.G556E | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs1417927879; called by muse, mutect2
- FGD2 | c.1029G>A p.L343= | Splice Region (SNP) | VAF 33/266 reads (12%) | catalogued as COSV51465116; called by muse, mutect2, varscan2
- FKBP14 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1330703003; called by muse, mutect2, varscan2
- FLG2 | c.2669G>A p.G890D | Missense Mutation (SNP) | VAF 189/614 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs370349464, COSV66174273; called by muse, mutect2, varscan2
- FLG2 | c.2668G>A p.G890S | Missense Mutation (SNP) | VAF 189/614 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs757892626; called by muse, mutect2, varscan2
- FLT4 | c.3956G>A p.R1319Q | Missense Mutation (SNP) | VAF 54/630 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.042); catalogued as rs145806915; called by muse, mutect2
- FMR1NB | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 42/366 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV63272717; called by muse, mutect2, varscan2
- FNDC7 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as rs551668665; called by muse, mutect2
- FOXP1 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 56/513 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV59526753; called by muse, mutect2, varscan2
- FRK | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 44/474 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs150259692; called by muse, mutect2
- FRMPD4 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 45/462 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV66211345; called by muse, mutect2, varscan2
- FSIP2 | c.17554G>A p.G5852R | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs769302788; called by muse, varscan2
- FTHL17 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 42/406 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV63266842; called by muse, mutect2
- FUT9 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.755); catalogued as rs146406553, COSV56142363; called by muse, mutect2, varscan2
- GABBR2 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 31/380 reads (8%) | SIFT tolerated, low confidence (0.49); PolyPhen probably damaging (0.979); catalogued as COSV52304102; called by muse, mutect2
- GABPA | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61395301; called by muse, mutect2
- GABRA4 | c.650A>T p.E217V | Missense Mutation (SNP) | VAF 38/361 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51935347; called by muse, mutect2, varscan2
- GABRG2 | c.1249-8C>T | Splice Region (SNP) | VAF 44/492 reads (9%) | catalogued as rs771660227; ClinVar: likely benign; called by muse, mutect2
- GALNT13 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 31/400 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV67216416; called by muse, mutect2
- GALNT6 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 40/373 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.52); catalogued as rs1455018815; called by muse, mutect2, varscan2
- GBP3 | c.1769C>T p.S590L | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1170352087, COSV52517656; called by muse, mutect2
- GCOM1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 52/544 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.212); catalogued as rs866578359, COSV51094729; called by muse, mutect2
- GHR | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as COSV50130813; called by muse, mutect2, varscan2
- GIMAP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100212318; called by muse, mutect2, varscan2
- GIMAP6 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 53/524 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV61032721; called by muse, mutect2
- GIT1 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs538711253, COSV99838114; called by muse, mutect2, varscan2
- GLIS3 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 34/458 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as rs778888638; called by muse, mutect2
- GLT6D1 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 56/526 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs190884433; called by muse, mutect2
- GLYAT | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.269); catalogued as rs752514559, COSV53538436; called by muse, mutect2
- GOLGB1 | c.8859G>A p.R2953= | Splice Region (SNP) | VAF 17/116 reads (15%) | catalogued as COSV100510411; called by muse, mutect2, varscan2
- GPATCH2L | c.151T>C p.F51L | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs776580028; called by muse, mutect2
- GPR68 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 44/472 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV53176303; called by muse, mutect2
- GPR83 | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 44/476 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as rs146036633, COSV99703654; called by muse, mutect2
- GPR83 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147783996; called by muse, mutect2, varscan2
- GPRASP1 | c.2117C>T p.S706L | Missense Mutation (SNP) | VAF 59/474 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs372366556, COSV64355830; called by muse, varscan2
- GPX6 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 54/564 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs761502681; called by muse, mutect2
- GRIA1 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 29/363 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1194364279, COSV53597870; called by muse, mutect2
- GRIK4 | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV104437173; called by muse, mutect2, varscan2
- GRIN2A | c.2945G>A p.G982E | Missense Mutation (SNP) | VAF 41/364 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs768295624; called by muse, mutect2, varscan2
- GRM3 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 54/443 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as rs571579021, COSV64471709, COSV64473083; called by muse, mutect2, varscan2
- GRXCR2 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1264319289, COSV65061327; called by muse, mutect2, varscan2
- GTPBP3 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.232); catalogued as COSV50196123; called by muse, mutect2, varscan2
- HAPLN1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs1422259616, COSV99165030; called by muse, mutect2, varscan2
- HCK | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 45/487 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs759226436; called by muse, mutect2
- HDC | c.1466A>G p.N489S | Missense Mutation (SNP) | VAF 40/493 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs748990320; called by muse, mutect2
- HDC | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 70/343 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs769839707, COSV51068917; called by muse, mutect2, varscan2
- HECW2 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 54/538 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV53670855; called by muse, mutect2
- HEPH | c.1138C>T p.R380* (on ENST00000343002; = p.R113* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 53/511 reads (10%) | catalogued as rs202143527, COSV57970020; called by muse, mutect2, varscan2
- HHIPL2 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 60/651 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.135); catalogued as rs1158980757, COSV58565623; called by muse, mutect2
- HID1 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 30/417 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1346197316; called by muse, mutect2
- HOXB2 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 75/579 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs752214609; called by muse, mutect2, varscan2
- HPSE2 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 42/359 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); catalogued as rs748636374, COSV65194458; called by muse, mutect2, varscan2
- HTR1B | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 48/534 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.372); catalogued as rs754049228; called by muse, mutect2
- HYDIN | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs267604623, COSV55485377; called by muse, varscan2
- ICAM2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 49/421 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs763561197; called by muse, mutect2, varscan2
- IDO1 | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.674); catalogued as rs1320569305, COSV104388985; called by muse, mutect2
- IGBP1P2 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 36/373 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1486529353; called by muse, mutect2
- IGF1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 47/437 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV61032220; called by muse, mutect2, varscan2
- IGFN1 | c.226A>G p.K76E | Missense Mutation (SNP) | VAF 117/419 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.026); catalogued as rs1295118067; called by muse, mutect2, varscan2
- IGHV2-70 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs568088145; called by muse, mutect2, varscan2
- IGHV3-23 | c.259T>C p.F87L | Missense Mutation (SNP) | VAF 34/479 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.603); catalogued as rs1555466943; called by muse, mutect2
- IGKV1-9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 32/492 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.11); catalogued as rs1252596130; called by muse, mutect2
- IGSF9 | c.2815G>A p.G939R (on ENST00000368094 / NM_001135050.2; = p.G923R on NM_020789.4) | Missense Mutation (SNP) | VAF 74/676 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs766150396; called by muse, mutect2, varscan2
- IL1R1 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV52107077; called by muse, mutect2, varscan2
- IL1RL1 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 28/399 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV52116318; called by muse, mutect2
- INPP5J | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 52/524 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1320229373; called by muse, mutect2
- IRF6 | c.1016G>A p.R339K | Missense Mutation (SNP) | VAF 48/477 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM081673, COSV65419147; called by muse, mutect2, varscan2
- IRS1 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 50/542 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.023); catalogued as rs765137973; called by muse, mutect2
- IRS4 | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 44/492 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64532884; called by muse, mutect2
- ISL1 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs759969078, COSV57932855, COSV57932880; called by muse, mutect2
- ITGAM | c.2797C>T p.H933Y (on ENST00000648685 / NM_001145808.2; = p.H932Y on NM_000632.4) | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as rs1255766887, COSV99792783; called by muse, mutect2, varscan2
- ITGAX | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 41/330 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as rs779296419, COSV51641307; called by muse, mutect2, varscan2
- ITGB4 | c.3376G>A p.D1126N | Missense Mutation (SNP) | VAF 46/476 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs199672740; called by muse, mutect2
- ITIH2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 45/260 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs375261970; called by muse, mutect2, varscan2
- ITM2A | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 33/315 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV64811908; called by muse, mutect2, varscan2
- KAT2B | c.2044C>T p.R682* | Nonsense Mutation (SNP) | VAF 32/314 reads (10%) | catalogued as COSV55428846; called by muse, mutect2, varscan2
- KCNAB1 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 61/424 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as rs150921882; called by muse, mutect2, varscan2
- KCNJ3 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as rs201650481, COSV54544929, COSV99716544; called by muse, mutect2, varscan2
- KCNT2 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 99/370 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs370788660; called by muse, mutect2, varscan2
- KCTD16 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.168); catalogued as COSV72578843; called by muse, mutect2
- KIAA1109 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52668013; called by muse, mutect2
- KIF16B | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 99/492 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.876); catalogued as COSV61702485, COSV61706284; called by muse, mutect2, varscan2
- KIF1A | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 48/404 reads (12%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV57487471; called by muse, varscan2
- KIF2B | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1356512215; called by muse, varscan2
- KIRREL3 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69386389; called by muse, mutect2, varscan2
- KLF18 | c.1871C>T p.A624V | Missense Mutation (SNP) | VAF 78/683 reads (11%) | SIFT tolerated (0.26); catalogued as rs888560445; called by muse, mutect2, varscan2
- KLHL1 | c.2219C>T p.A740V | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs773336015; called by muse, mutect2
- KLK15 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1316682471; called by muse, mutect2, varscan2
- KMT2B | c.3061C>T p.R1021W | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753991431; called by muse, mutect2, varscan2
- KNTC1 | c.6073C>T p.P2025S | Missense Mutation (SNP) | VAF 29/355 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99048626; called by muse, mutect2
- KRT23 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 39/365 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1445152943; called by muse, mutect2, varscan2
- KRTAP11-1 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 43/464 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as rs762481221; called by muse, mutect2
- LAMB4 | c.205T>G p.C69G | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs773325660; called by muse, mutect2, varscan2
- LAS1L | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 32/339 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as COSV56709031; called by muse, mutect2
- LELP1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 70/724 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); catalogued as rs761668608, COSV64202571; called by muse, mutect2
- LENG8 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 57/556 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs770218881; called by muse, mutect2
- LEUTX | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.538); catalogued as rs1029970572; called by muse, mutect2, varscan2
- LGALS13 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV99032465; called by muse, mutect2
- LGSN | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs868211176, COSV65728092; called by muse, mutect2, varscan2
- LIFR | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.108); catalogued as rs761994189; called by muse, mutect2, varscan2
- LINC00514 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as rs985387945; called by muse, mutect2
- LOXL2 | c.1618G>A p.G540R | Missense Mutation (SNP) | VAF 54/497 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369018704, COSV66692546; called by muse, mutect2, varscan2
- LPA | c.4700C>T p.P1567L | Missense Mutation (SNP) | VAF 32/506 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs1230957395, COSV60313901; called by muse, mutect2
- LPA | c.2980C>T p.P994S | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV60300473; called by muse, mutect2
- LRFN2 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 54/550 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.97); catalogued as rs766153599, COSV100599278; called by muse, mutect2
- LRP1B | c.7154G>A p.G2385E | Missense Mutation (SNP) | VAF 26/377 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV67186728; called by muse, mutect2
- LRP1B | c.3769C>T p.P1257S | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV67197601; called by muse, mutect2
- LRP1B | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 38/335 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1423412691, COSV67188779, COSV67197611; called by muse, mutect2, varscan2
- LRRC10 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 27/286 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100825513; called by muse, mutect2
- LRRC7 | c.1570G>A p.E524K (on ENST00000651989 / NM_001370785.2; = p.E491K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs866086728, COSV50412443; called by muse, mutect2, varscan2
- LRRD1 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100588133, COSV58471629; called by muse, mutect2
- LRRIQ1 | c.2702C>T p.S901F | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs773796685; called by muse, mutect2
- LTBP2 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 55/506 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1444940663; called by muse, mutect2, varscan2
- MACO1 | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs759726969, COSV65476150; called by muse, mutect2, varscan2
- MAGEC1 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 68/619 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1178375590; called by muse, mutect2, varscan2
- MAGI2 | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1411461622; called by muse, mutect2, varscan2
- MAGI2 | c.3022C>T p.P1008S | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs764279398; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAPK9 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs1361309771; called by muse, mutect2, varscan2
- MARCHF8 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 49/460 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs141581157; called by muse, mutect2, varscan2
- MAVS | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 50/624 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs375947622; called by muse, mutect2
- MEF2A | c.862G>A p.E288K (on ENST00000557942 / NM_001319206.2; = p.E220K on NM_001130927.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs371903721; called by muse, mutect2
- MEGF6 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 40/346 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs1314808564, COSV100742195; called by muse, mutect2, varscan2
- MEPE | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772909804; called by muse, mutect2
- METTL25 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs749469219; called by muse, mutect2, varscan2
- MGAM | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV71885992; called by muse, mutect2, varscan2
- MICB | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs772520548, COSV52857399; called by muse, mutect2
- MROH2B | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68180822, COSV68182913; called by muse, mutect2, varscan2
- MSLN | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 53/388 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs561074472; called by muse, mutect2, varscan2
- MUC16 | c.30689C>T p.P10230L | Missense Mutation (SNP) | VAF 45/443 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs1240233308, COSV67480178; called by muse, mutect2, varscan2
- MUC16 | c.26542G>A p.E8848K | Missense Mutation (SNP) | VAF 45/433 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs758682809, COSV67446748, COSV67446844; called by muse, mutect2, varscan2
- MUC16 | c.22934C>T p.S7645F | Missense Mutation (SNP) | VAF 44/414 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.371); catalogued as rs771006147; called by muse, mutect2, varscan2
- MUC16 | c.5314G>A p.E1772K | Missense Mutation (SNP) | VAF 49/432 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV101201332; called by muse, mutect2, varscan2
- MUC16 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 55/424 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.197); catalogued as rs769571404, COSV67446414; called by muse, mutect2, varscan2
- MUC19 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 47/376 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs966689002; called by muse, mutect2, varscan2
- MUTYH | c.1321C>T p.H441Y | Missense Mutation (SNP) | VAF 32/307 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1475410456, COSV100588168; called by muse, mutect2, varscan2
- MX1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs759064575; called by muse, mutect2, varscan2
- MYH1 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 39/401 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV56844397; called by muse, mutect2, varscan2
- MYH11 | c.5029G>A p.E1677K | Missense Mutation (SNP) | VAF 52/411 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as rs1342104521; called by muse, mutect2, varscan2
- MYH13 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52836542; called by muse, varscan2
- MYH2 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 30/462 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55433645; called by muse, mutect2
- MYH2 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 45/426 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs772963819, COSV55430947; called by muse, mutect2, varscan2
- MYH8 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 29/323 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs751752898; called by muse, mutect2
- MYLPF | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 43/373 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs1343382147; called by muse, mutect2, varscan2
- MYO10 | c.4055C>T p.S1352L | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs201643495, COSV57027919; called by muse, mutect2
- MYO15A | c.3866C>T p.P1289L | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192483691, COSV52762367, COSV99234164; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18B | c.2819C>T p.S940F | Missense Mutation (SNP) | VAF 26/407 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59136172; called by muse, mutect2
- MYOM2 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 70/633 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs149104727; called by muse, mutect2, varscan2
- NASP | c.1420G>A p.G474S | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs933284329; called by muse, mutect2, varscan2
- NCAN | c.2653C>T p.P885S | Missense Mutation (SNP) | VAF 55/536 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.099); catalogued as COSV53055779; called by muse, mutect2
- NCR1 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 50/560 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as COSV52557105; called by muse, mutect2
- NDOR1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1451702405; called by muse, mutect2, varscan2
- NDUFS2 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs932640288, COSV57154508; called by muse, mutect2
- NEBL | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 42/443 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs774594552, COSV65801829; called by muse, mutect2
- NEBL | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV65799568; called by muse, mutect2, varscan2
- NEIL1 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs534821044; called by muse, mutect2, varscan2
- NEU1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 46/545 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1160927051, COSV57666860; called by muse, mutect2
- NF1 | c.1302del p.H435Tfs*38 | Frame Shift Del (DEL) | VAF 28/275 reads (10%) | catalogued as CM153408; called by mutect2, pindel, varscan2
- NFKBIE | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 53/529 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV51487728; called by muse, mutect2, varscan2
- NLGN3 | c.559G>A p.D187N (on ENST00000358741 / NM_181303.2; = p.D167N on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/448 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV62444940; called by muse, mutect2, varscan2
- NLRP7 | c.2810+1G>A p.X937_splice (on ENST00000340844 / NM_206828.3; = p.X909_splice on NM_139176.3) | Splice Site (SNP) | VAF 23/207 reads (11%) | catalogued as COSV60172834; called by muse, mutect2, varscan2
- NLRP8 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs752687742, COSV52583722; called by muse, mutect2
- NONO | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 46/380 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV52136998, COSV52138484; called by muse, mutect2, varscan2
- NPIPB2 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.999); catalogued as rs750180686, COSV67689863; called by muse, mutect2, varscan2
- NPM3 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 49/427 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63383097; called by muse, mutect2, varscan2
- NPY2R | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 34/414 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs1435941045; called by muse, mutect2
- NPY5R | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs867560945, COSV58451014; called by muse, mutect2
- NRXN3 | c.797G>A p.G266E (on ENST00000557594 / NM_001272020.2; = p.G898E on NM_004796.6) | Missense Mutation (SNP) | VAF 43/496 reads (9%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.474); catalogued as rs547163993, COSV55326802; called by muse, mutect2
- NT5C1A | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 56/438 reads (13%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.625); catalogued as rs778318977, COSV52493856; called by muse, mutect2, varscan2
- NT5C1B | c.502C>T p.P168S (on ENST00000359846 / NM_001199086.2; = p.P108S on NM_033253.4) | Missense Mutation (SNP) | VAF 44/520 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV58395644; called by muse, mutect2
- NTM | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 35/327 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV66267647; called by muse, mutect2, varscan2
- NTRK3 | c.2203C>T p.R735C (on ENST00000360948 / NM_001012338.2; = p.R721C on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/333 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478926904, COSV62300291; called by muse, mutect2, varscan2
- NUP210 | c.3200G>A p.R1067K | Missense Mutation (SNP) | VAF 41/416 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99596234; called by muse, mutect2
- NUTM1 | c.2935A>G p.T979A | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV59215963; called by muse, mutect2
- NXNL2 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs1034212619; called by muse, varscan2
- NXPE1 | c.836C>T p.S279F (on ENST00000424269; = p.S137F on NM_152315.5) | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as COSV52626640; called by muse, mutect2
- NYAP2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 47/339 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs760029500, COSV56003082, COSV99795347; called by muse, mutect2, varscan2
- OBSCN | c.9391G>A p.D3131N | Missense Mutation (SNP) | VAF 53/768 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as rs368127118; called by muse, mutect2
- OBSCN | c.9832G>A p.G3278R | Missense Mutation (SNP) | VAF 88/284 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.036); catalogued as rs750419068, COSV99478651; called by muse, mutect2, varscan2
- OBSCN | c.14242C>T p.R4748C | Missense Mutation (SNP) | VAF 204/651 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs373985115; called by muse, varscan2
- OCSTAMP | c.1050G>A p.V350= | Splice Region (SNP) | VAF 26/229 reads (11%) | catalogued as rs1482917396; called by muse, mutect2, varscan2
- OGFRL1 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 53/456 reads (12%) | catalogued as rs746194897, COSV64971712; called by muse, mutect2, varscan2
- OLFML2A | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 61/475 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59160507; called by muse, mutect2, varscan2
- OPN5 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 41/396 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1403207027, COSV55247759; called by muse, mutect2, varscan2
- OR10J3 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 179/567 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV59955593; called by muse, varscan2
- OR10J5 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 42/562 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV58384756; called by muse, mutect2
- OR11H1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 21/506 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs1290504048; called by muse, mutect2
- OR1A1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 35/439 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.06); catalogued as rs765272168, COSV58404653; called by muse, mutect2
- OR2A5 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 24/546 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as rs902648333, COSV101278875; called by muse, mutect2
- OR2AK2 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 40/405 reads (10%) | catalogued as rs767778692, COSV100822935; called by muse, mutect2, varscan2
- OR2H2 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 75/653 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.461); catalogued as rs543768371, COSV100589891; called by muse, mutect2, varscan2
- OR2T1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 68/953 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs769406328, COSV63541354; called by muse, mutect2
- OR2T11 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 139/411 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.391); catalogued as COSV58185321; called by muse, mutect2, varscan2
- OR2T33 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 44/449 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as rs1341758711, COSV58816981, COSV58817423; called by muse, mutect2, varscan2
- OR2V2 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 50/552 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401311748; called by muse, mutect2
- OR4K5 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 40/663 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1275287058, COSV60005258, COSV60005593; called by muse, mutect2
- OR4K5 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs868852438; called by muse, mutect2
- OR51B4 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV66517004; called by muse, mutect2
- OR51B5 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 38/384 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1435926857, COSV56175601; called by muse, mutect2
- OR52E1 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 39/271 reads (14%) | catalogued as rs915136460; called by muse, mutect2, varscan2
- OR52N5 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 48/449 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.023); catalogued as COSV100399629; called by muse, mutect2, varscan2
- OR5A2 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 41/321 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as rs751253917; called by muse, mutect2, varscan2
- OR5D14 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs1289566006; called by muse, mutect2, varscan2
- OR5K1 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 41/315 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV60303472, COSV60305360; called by muse, mutect2, varscan2
- OR5M3 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 34/472 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV56565735; called by muse, mutect2
- OR6C6 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 26/301 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as rs981517436; called by muse, mutect2
- OR8D1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 49/429 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868159781, COSV63442418; called by muse, mutect2, varscan2
- OSGEP | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 47/340 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs374503423; called by muse, mutect2, varscan2
- P2RY14 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 58/359 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as rs139156564; called by muse, mutect2, varscan2
- PALB2 | c.1777C>T p.H593Y | Missense Mutation (SNP) | VAF 42/494 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV55162332; called by muse, mutect2
- PAPLN | c.1829C>T p.P610L (on ENST00000554301; = p.P583L on NM_173462.4) | Missense Mutation (SNP) | VAF 62/683 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99389360; called by muse, mutect2
- PARD3 | c.3862C>T p.R1288C | Missense Mutation (SNP) | VAF 43/486 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1455800980; called by muse, mutect2
- PARP12 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV99694169; called by muse, mutect2
- PBX1 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 31/276 reads (11%) | catalogued as rs1259895025; called by muse, varscan2
- PCDH10 | c.782A>T p.E261V | Missense Mutation (SNP) | VAF 53/498 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52101433; called by muse, mutect2
- PCDH15 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs1281151581, COSV57287031; called by muse, mutect2, varscan2
- PCDHA13 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 70/561 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56515710; called by muse, mutect2, varscan2
- PCDHA8 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs141101675; called by muse, varscan2
- PCDHB12 | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 64/838 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV53393571; called by muse, mutect2
- PCDHB13 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 76/850 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs781872111, COSV53397012; called by muse, mutect2
- PCDHB4 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1430590866, COSV52019621; called by muse, mutect2, varscan2
- PCLO | c.7222C>T p.P2408S | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs750559282; called by muse, mutect2, varscan2
- PDZD11 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 56/445 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52105056, COSV52105271; called by muse, mutect2, varscan2
- PEAR1 | c.2959C>T p.H987Y | Missense Mutation (SNP) | VAF 44/476 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1425218250, COSV52770662; called by muse, mutect2
- PEX11B | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 48/616 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376116716; ClinVar: uncertain significance; called by muse, mutect2
- PEX5L | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.063); catalogued as COSV55848021; called by muse, mutect2, varscan2
- PGLYRP3 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 122/427 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51950279; called by muse, mutect2, varscan2
- PHLDB2 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.014); catalogued as rs1160303709, COSV101208688; called by muse, mutect2
- PHTF1 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 33/354 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs368409808; called by muse, mutect2
- PIK3C2G | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99853523; called by muse, mutect2, varscan2
- PLCB3 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 45/451 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs267603096, COSV54192465; called by muse, mutect2
- PLCH1 | c.4159C>T p.P1387S (on ENST00000340059 / NM_001130960.2; = p.P1379S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.048); catalogued as COSV58210608; called by muse, mutect2, varscan2
- PLEKHG3 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 43/483 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529562926; called by muse, mutect2
- PLG | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs369616186; called by muse, mutect2
- PLPPR1 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 24/324 reads (7%) | catalogued as COSV66449638; called by muse, mutect2
- PLSCR3 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 42/409 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.266); catalogued as COSV61169912; called by muse, mutect2, varscan2
- PLXNB1 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.853); catalogued as COSV56494879; called by muse, mutect2
- PM20D2 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 41/295 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as rs933939372; called by muse, mutect2, varscan2
- PMFBP1 | c.1783C>T p.R595C (on ENST00000537465; = p.R590C on NM_031293.3) | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs149578677, COSV99401367; called by muse, mutect2, varscan2
- POLE | c.6262C>T p.P2088S | Missense Mutation (SNP) | VAF 42/386 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as rs749342382, COSV57680735; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLH | c.1936G>T p.D646Y | Missense Mutation (SNP) | VAF 48/455 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs772437063; called by muse, mutect2, varscan2
- POM121L12 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 52/580 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.451); catalogued as COSV68692767; called by muse, mutect2
- POM121L12 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 58/596 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as rs541507226, COSV68692510; called by muse, mutect2
- POTEI | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as rs1189718928; called by muse, mutect2
- PPFIA2 | c.3665G>A p.G1222E | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV61051144; called by muse, mutect2, varscan2
- PPFIA2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99048593; called by muse, mutect2, varscan2
- PPIAL4G | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 85/795 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1553321561, COSV70086718; called by muse, mutect2, varscan2
- PPP1R3A | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777577225, COSV52880562; called by muse, mutect2, varscan2
- PPP4R3C | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1040973186; called by muse, mutect2
- PRAMEF19 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as rs764227712, COSV65820310; called by muse, mutect2, varscan2
- PRAMEF2 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.502); catalogued as rs140567467; called by mutect2, varscan2
- PREX2 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 138/510 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs200411060, COSV99908878; called by muse, mutect2, varscan2
- PREX2 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 191/587 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs868582467, COSV55755180; called by muse, mutect2, varscan2
- PRKACG | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 48/425 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV55251112; called by muse, mutect2, varscan2
- PRMT8 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV54212391, COSV54220255; called by muse, mutect2
- PROC | c.162C>G p.S54R | Missense Mutation (SNP) | VAF 45/428 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as CM005570, COSV52165035; called by muse, mutect2, varscan2
- PRORP | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs147065101; called by muse, mutect2, varscan2
- PRSS41 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 46/427 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs375742876; called by muse, mutect2
- PRSS45P | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 79/452 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.388); catalogued as rs751920872, COSV101373888; called by muse, mutect2, varscan2
- PSD2 | c.1617G>A p.W539* | Nonsense Mutation (SNP) | VAF 59/357 reads (17%) | catalogued as COSV51210846; called by muse, mutect2, varscan2
- PSG4 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs765839412; called by muse, mutect2
- PSG6 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1398812733, COSV51838168; called by muse, mutect2, varscan2
- PSG9 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs764914188; called by muse, mutect2, varscan2
- PTGFR | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 57/414 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66114765; called by muse, mutect2, varscan2
- PTPRD | c.2420G>A p.G807E | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61939913; called by muse, mutect2
- PTPRD | c.1498G>C p.D500H | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61966072, COSV61971833; called by muse, mutect2
- PTPRG | c.4120G>A p.E1374K | Missense Mutation (SNP) | VAF 40/520 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV55627585; called by muse, mutect2
- PTPRT | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 47/655 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.232); catalogued as rs767338819; called by muse, mutect2
- RAVER2 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 57/398 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53809581; called by muse, mutect2, varscan2
- RB1CC1 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 36/462 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV50243534; called by muse, mutect2
- RBBP6 | c.4607C>T p.P1536L | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV60508173; called by muse, mutect2, varscan2
- RBM19 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 42/361 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs774088254; called by muse, mutect2, varscan2
- REEP1 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 33/256 reads (13%) | catalogued as COSV51255688; called by muse, mutect2, varscan2
- RERE | c.3112C>T p.P1038S | Missense Mutation (SNP) | VAF 45/418 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs965223899; called by muse, mutect2
- RGP1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as COSV100960277; called by muse, mutect2, varscan2
- RGS4 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 123/400 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV63356821; called by muse, mutect2, varscan2
- RIMBP2 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 43/412 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs771459544, COSV99899018; called by muse, mutect2, varscan2
- RND1 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 39/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59044819; called by muse, mutect2, varscan2
- RNF123 | c.3721G>A p.A1241T | Missense Mutation (SNP) | VAF 21/319 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs1234914611; called by muse, mutect2
- ROM1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 42/431 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs764120836, COSV99605630; called by muse, mutect2
- RPA4 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 51/432 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.044); catalogued as rs148408114; called by muse, mutect2, varscan2
- RUBCN | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 55/465 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs991833469; called by muse, mutect2, varscan2
- RUNX1T1 | c.1429G>A p.D477N (on ENST00000265814 / NM_001198628.1; = p.D450N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/560 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs569622614, COSV56148600; called by muse, mutect2, varscan2
- RUSC2 | c.3790C>T p.R1264* | Nonsense Mutation (SNP) | VAF 63/598 reads (11%) | catalogued as COSV63429721; called by muse, mutect2, varscan2
- S100A12 | c.46C>T p.H16Y | Missense Mutation (SNP) | VAF 111/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149178986; called by muse, mutect2, varscan2
- S1PR1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs756873576, COSV59513305; called by muse, mutect2
- SACM1L | c.1096T>A p.L366I | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs970278843; called by muse, mutect2, varscan2
- SAMD9L | c.1682T>C p.I561T | Missense Mutation (SNP) | VAF 37/363 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs921789574; called by muse, mutect2, varscan2
- SAMSN1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 40/442 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs764770832; called by muse, mutect2
- SASH3 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 60/720 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1444194777; called by muse, mutect2
- SCN10A | c.5777G>A p.R1926K | Missense Mutation (SNP) | VAF 42/453 reads (9%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.629); catalogued as rs756396678, COSV101479428; called by muse, mutect2
- SCN10A | c.4165G>A p.E1389K | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71861087; called by muse, mutect2
- SCN10A | c.1583G>A p.G528E | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV71862771; called by muse, mutect2
- SCN2A | c.4585A>G p.T1529A | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV51834449; called by muse, mutect2, varscan2
- SCN3A | c.4889G>A p.R1630Q | Missense Mutation (SNP) | VAF 58/515 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs1559175180, COSV51810485; called by muse, mutect2, varscan2
- SEC23B | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 51/320 reads (16%) | catalogued as rs368960604, CM108330, COSV52718576, COSV52719559; called by muse, mutect2, varscan2
- SEC23IP | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs769414189; called by muse, varscan2
- SF3B2 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs886460919; called by muse, mutect2, varscan2
- SFMBT1 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 34/412 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1321262516, COSV99965908; called by muse, mutect2
- SFTPD | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 57/449 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142628179; called by muse, mutect2, varscan2
- SGTA | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs1397735810; called by muse, mutect2
- SH3RF2 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as COSV100767663; called by muse, mutect2
- SHROOM2 | c.3506C>T p.S1169L | Missense Mutation (SNP) | VAF 85/642 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs775435312, COSV66604634; called by muse, mutect2, varscan2
- SIGLEC5 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV55783613; called by muse, mutect2
- SLC17A1 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV55077224; called by muse, varscan2
- SLC26A5 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59702599, COSV59702745; called by muse, mutect2
- SLC27A6 | c.1692G>A p.M564I | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as COSV52483902, COSV99321937; called by muse, mutect2
- SLC35F2 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 26/277 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1292017220, COSV99758836; called by muse, mutect2
- SLC36A1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 32/321 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54652429; called by muse, mutect2, varscan2
- SLC36A3 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111989476, COSV100077364; called by muse, mutect2
- SLC4A4 | c.3142C>T p.P1048S (on ENST00000264485 / NM_001098484.3; = p.P1004S on NM_003759.4) | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as COSV99142529; called by muse, mutect2
- SLC6A19 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as rs182081474; called by muse, mutect2, varscan2
- SLC7A13 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 216/633 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99879159; called by muse, mutect2, varscan2
- SLC7A14 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as rs910283268; called by muse, varscan2
- SLC9A4 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 32/315 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs1303324637, COSV99763209; called by muse, mutect2, varscan2
- SLIT1 | c.4381G>A p.G1461R | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56599056; called by muse, mutect2
- SLIT3 | c.3391G>A p.G1131R | Missense Mutation (SNP) | VAF 58/466 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs778244564, COSV100267366, COSV60590756; called by muse, mutect2, varscan2
- SLITRK3 | c.2356G>A p.G786R | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.419); catalogued as COSV99579288; called by muse, mutect2, varscan2
- SMG8 | c.1939C>T p.H647Y | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.427); catalogued as rs139959281; called by muse, mutect2, varscan2
- SNCAIP | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs267600329, COSV54401647; called by muse, varscan2
- SNRNP200 | c.3184C>T p.L1062F | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100108073; called by muse, mutect2
- SNRPB | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 36/328 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.981); catalogued as COSV60015749; called by muse, mutect2, varscan2
- SORBS2 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 40/472 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs530628406; called by muse, mutect2
- SORCS3 | c.2130A>T p.G710= | Splice Region (SNP) | VAF 30/194 reads (15%) | catalogued as rs375060365; called by muse, mutect2, varscan2
- SPATA31A1 | c.1583C>T p.S528L | Missense Mutation (SNP) | VAF 63/722 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1249517395; called by muse, mutect2
- SPEF2 | c.3110C>T p.S1037F | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs752773618, COSV61547667; called by muse, mutect2, varscan2
- SPHKAP | c.2510G>A p.G837E | Missense Mutation (SNP) | VAF 42/418 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV60868662; called by muse, mutect2
- SPHKAP | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 42/500 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV60894326; called by muse, mutect2
- SPTAN1 | c.4819C>A p.R1607S | Missense Mutation (SNP) | VAF 51/394 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.223); catalogued as COSV63989358, COSV63990164; called by muse, mutect2, varscan2
- SPTLC3 | c.378G>A p.W126* | Nonsense Mutation (SNP) | VAF 58/615 reads (9%) | catalogued as COSV100983002; called by muse, mutect2
- STAB1 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 37/458 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201122593, COSV58732440; called by muse, mutect2
- STAB2 | c.4933C>T p.R1645W | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs781561788, COSV101185894; called by muse, mutect2
- STYXL2 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 68/608 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.738); catalogued as rs868046934; called by muse, mutect2, varscan2
- SUSD4 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 210/657 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as COSV59552106; called by muse, mutect2, varscan2
- SYNPO2 | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 52/473 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as rs759612951; called by muse, mutect2, varscan2
- SYPL1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs11545139; called by muse, mutect2, varscan2
- SYT17 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 45/388 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs779389450; called by muse, mutect2, varscan2
- TACR1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 41/366 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV59482466; called by muse, mutect2, varscan2
- TAF1 | c.3377G>A p.R1126K (on ENST00000373790 / NM_138923.4; = p.R1147K on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/406 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52124679; called by muse, mutect2, varscan2
- TAS2R39 | c.456G>A p.W152* | Nonsense Mutation (SNP) | VAF 36/492 reads (7%) | catalogued as rs867540296, COSV101489409; called by muse, mutect2
- TBX18 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 40/442 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV63736433; called by muse, mutect2
- TEK | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs866968099, COSV66230376; called by muse, mutect2, varscan2
- TENT5D | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 53/415 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); catalogued as rs538071284; called by muse, mutect2
- TEX13D | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs1312067613; called by muse, mutect2, varscan2
- TEX14 | c.1136C>T p.S379F (on ENST00000240361 / NM_001201457.2; = p.S373F on NM_031272.5) | Missense Mutation (SNP) | VAF 55/442 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53629576; called by muse, mutect2, varscan2
- TGFBR3L | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 64/665 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.336); catalogued as COSV55603297; called by muse, mutect2
- TGM6 | c.425-1G>A p.X142_splice | Splice Site (SNP) | VAF 26/310 reads (8%) | catalogued as rs1290768586; called by muse, mutect2
- TGM6 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 71/374 reads (19%) | catalogued as rs575622127, COSV52478321, COSV99171659; called by muse, mutect2, varscan2
- THEG | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 52/481 reads (11%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as COSV61073275; called by muse, mutect2, varscan2
- THSD7B | c.2378C>T p.S793F | Missense Mutation (SNP) | VAF 15/313 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs1347902701, COSV55656405; called by muse, mutect2
- TKTL1 | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 44/346 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.74); catalogued as rs782618468, COSV99474009; called by muse, mutect2, varscan2
- TKTL2 | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 47/391 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs867327952; called by muse, mutect2, varscan2
- TLR4 | c.673G>A p.E225K (on ENST00000355622 / NM_138554.5; = p.E185K on NM_003266.4) | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV62922585, COSV62922718; called by muse, mutect2
- TMC7 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as rs1421326683; called by muse, mutect2, varscan2
- TMEM185A | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 38/354 reads (11%) | catalogued as COSV57560417; called by muse, mutect2, varscan2
- TMEM200C | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 54/510 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750394153, COSV67309219; called by mutect2, varscan2
- TMEM30A | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs749052661, COSV57875496; called by muse, mutect2, varscan2
- TNFRSF4 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs900557992; called by muse, mutect2, varscan2
- TNFSF10 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.535); catalogued as rs1210164777; called by muse, mutect2, varscan2
- TNR | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 44/490 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.924); catalogued as COSV54886624; called by muse, mutect2
- TNRC18 | c.2635C>T p.P879S | Missense Mutation (SNP) | VAF 51/432 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV68164130; called by muse, mutect2, varscan2
- TNRC18 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 66/593 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs775989406; called by muse, mutect2, varscan2
- TOGARAM2 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 41/372 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs570629655; called by muse, mutect2, varscan2
- TOGARAM2 | c.101C>A p.P34Q | Missense Mutation (SNP) | VAF 40/366 reads (11%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.511); catalogued as rs996854246, COSV65420710; called by muse, mutect2, varscan2
- TOP2B | c.2071G>A p.E691K (on ENST00000264331 / NM_001330700.2; = p.E686K on NM_001068.3) | Missense Mutation (SNP) | VAF 55/306 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as COSV51970500; called by muse, mutect2, varscan2
- TRAJ40 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 26/347 reads (7%) | catalogued as rs1461949860; called by muse, mutect2
- TREM1 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 49/438 reads (11%) | PolyPhen benign (0.438); catalogued as rs373247477; called by muse, mutect2, varscan2
- TRIM31 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 56/688 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.32); catalogued as rs761494388, COSV100946731; called by muse, mutect2
- TRIML1 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100206151; called by muse, mutect2
- TRIML1 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.993); catalogued as COSV60196617; called by muse, mutect2
- TRPC7 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 38/454 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); catalogued as rs1164275793, COSV61459294; called by muse, mutect2
- TSHZ2 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 47/436 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61591164; called by muse, mutect2, varscan2
- TSPEAR | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs782669581; called by muse, mutect2
- TTBK2 | c.2752C>T p.H918Y | Missense Mutation (SNP) | VAF 102/486 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.076); catalogued as COSV51185442; called by muse, mutect2, varscan2
- TTC6 | c.487G>A p.G163R (on ENST00000267368; = p.G1529R on NM_001310135.3) | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1325228894; called by muse, mutect2, varscan2
- TTLL4 | c.3452C>T p.S1151F | Missense Mutation (SNP) | VAF 63/495 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV51437594; called by muse, mutect2, varscan2
- TTN | c.52064A>T p.K17355I (on ENST00000591111; = p.K9931I on NM_003319.4) | Missense Mutation (SNP) | VAF 39/308 reads (13%) | PolyPhen possibly damaging (0.894); catalogued as COSV59916156, COSV60169504; called by muse, mutect2, varscan2
- TTN | c.37306C>T p.L12436F (on ENST00000591111; = p.L5012F on NM_003319.4) | Missense Mutation (SNP) | VAF 34/342 reads (10%) | PolyPhen possibly damaging (0.775); catalogued as rs758746920, COSV59982324; called by muse, mutect2, varscan2
- UGT2B4 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 40/400 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59319693; called by muse, mutect2
- UGT2B4 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1207803837, COSV59318186; called by muse, mutect2
- ULK2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 35/368 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100860658; called by muse, mutect2
- UNC5D | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV54778877; called by muse, mutect2, varscan2
- UNC5D | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 102/471 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54795571; called by muse, mutect2, varscan2
- UNC80 | c.3922G>A p.D1308N | Missense Mutation (SNP) | VAF 39/381 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs899960452, COSV55885283; called by muse, mutect2, varscan2
- UNC80 | c.4013C>T p.P1338L | Missense Mutation (SNP) | VAF 35/409 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55892941; called by muse, mutect2
- UNC80 | c.6400C>T p.P2134S | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1487236152; called by muse, mutect2, varscan2
- UPB1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 44/369 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs372357415; called by muse, mutect2, varscan2
- UPP2 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 46/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs949766164; called by muse, mutect2, varscan2
- USH1C | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); catalogued as rs924642642; called by muse, mutect2, varscan2
- USH2A | c.1343C>A p.S448Y | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100240452; called by muse, mutect2, varscan2
- USO1 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769649673; called by muse, mutect2
- USP17L2 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 102/1004 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.115); catalogued as COSV61555698; called by muse, mutect2, varscan2
- USP34 | c.10181C>T p.S3394L | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as rs757974206; called by muse, mutect2
- USP6 | c.3613G>A p.G1205R | Missense Mutation (SNP) | VAF 46/408 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs761598047; called by muse, mutect2, varscan2
- USP6 | c.3614G>A p.G1205E | Missense Mutation (SNP) | VAF 46/408 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1329007630; called by muse, mutect2, varscan2
- VWF | c.2942C>T p.S981F | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.942); catalogued as rs1484529401; called by muse, mutect2, varscan2
- VWF | c.2018C>T p.S673F | Missense Mutation (SNP) | VAF 51/413 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54630513; called by muse, mutect2, varscan2
- WASHC5 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 131/468 reads (28%) | catalogued as COSV59198944; called by muse, mutect2, varscan2
- WDR38 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1312879176; called by muse, mutect2, varscan2
- WEE2 | c.836G>A p.W279* | Nonsense Mutation (SNP) | VAF 33/321 reads (10%) | catalogued as rs1450503710; called by muse, mutect2, varscan2
- WLS | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs776089916, COSV61343126; called by muse, mutect2, varscan2
- XDH | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754593222, COSV65150498; called by muse, mutect2
- XIRP1 | c.5006C>T p.S1669F | Missense Mutation (SNP) | VAF 43/467 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61138480; called by muse, mutect2
- XIRP2 | c.7942C>T p.Q2648* (on ENST00000628543; = p.Q2823* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 51/403 reads (13%) | catalogued as COSV99743205; called by muse, mutect2, varscan2
- XKR3 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 55/450 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV58885446; called by muse, mutect2, varscan2
- XKR6 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 95/570 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58654569; called by muse, mutect2, varscan2
- XYLT1 | c.1937A>G p.D646G | Missense Mutation (SNP) | VAF 57/484 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV54489916; called by muse, mutect2, varscan2
- ZFHX4 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 177/532 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.996); catalogued as rs545258517, COSV51497475, COSV99269181; called by muse, mutect2, varscan2
- ZFHX4 | c.3505G>A p.D1169N | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV51440188; called by muse, mutect2
- ZFHX4 | c.8572G>A p.E2858K | Missense Mutation (SNP) | VAF 52/600 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as COSV51490543; called by muse, mutect2
- ZFP69B | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV64314995; called by muse, mutect2, varscan2
- ZFPM2 | c.2777C>T p.S926F | Missense Mutation (SNP) | VAF 168/513 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.416); catalogued as rs749656717, COSV65872951; called by muse, mutect2, varscan2
- ZFYVE26 | c.5584C>T p.R1862C | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs772855517; called by muse, mutect2
- ZMYND12 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); catalogued as rs771190256; called by muse, mutect2
- ZNF211 | c.1523C>T p.P508L (on ENST00000347302 / NM_198855.4; = p.P521L on NM_006385.5) | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs772904034; called by muse, mutect2
- ZNF257 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as COSV71306834; called by muse, mutect2, varscan2
- ZNF267 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 26/387 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs777542126; called by muse, mutect2
- ZNF331 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 39/405 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs757858629; called by muse, mutect2, varscan2
- ZNF532 | c.3245G>A p.R1082K | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.481); catalogued as rs34512035, COSV60175617; called by muse, mutect2, varscan2
- ZNF549 | c.1118C>T p.S373F (on ENST00000376233 / NM_001199295.2; = p.S360F on NM_153263.2) | Missense Mutation (SNP) | VAF 50/414 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV53725622; called by muse, mutect2, varscan2
- ZNF560 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 38/399 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.492); catalogued as COSV56868878; called by muse, mutect2, varscan2
- ZNF574 | c.2189C>T p.A730V | Missense Mutation (SNP) | VAF 50/406 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs147573884; called by muse, varscan2
- ZNF66 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 32/343 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs1483591417; called by muse, mutect2
- ZNF679 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 27/271 reads (10%) | catalogued as COSV55382429; called by muse, mutect2
- ZNF705A | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as COSV63733802; called by muse, mutect2, varscan2
- ZNF732 | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 44/469 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1246463365, COSV101339148; called by muse, mutect2, varscan2
- ZNF750 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 51/446 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs757683345; called by muse, mutect2, varscan2
- ZNF804B | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV60826722; called by muse, mutect2, varscan2
- ZNF831 | c.3347C>T p.S1116L | Missense Mutation (SNP) | VAF 64/559 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1191218602, COSV64044887; called by muse, mutect2, varscan2
- ZNF99 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68056153; called by muse, mutect2
- ABCA8 | c.3761A>T p.K1254I | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ABCC9 | c.1931G>A p.R644K | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ABCG1 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 43/286 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABI3BP | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 33/278 reads (12%) | called by muse, mutect2, varscan2
- AC011005.1 | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 40/369 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC114490.3 | c.112A>T p.R38* | Nonsense Mutation (SNP) | VAF 32/340 reads (9%) | called by muse, mutect2
- ACAN | c.5348C>G p.T1783S | Missense Mutation (SNP) | VAF 57/464 reads (12%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACAN | c.6578G>A p.G2193E | Missense Mutation (SNP) | VAF 54/449 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ACLY | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, varscan2
- ACOX2 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 45/433 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ACVRL1 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM29 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 51/413 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ADAM29 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 44/502 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- ADAMTS18 | c.2171G>A p.G724E | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTSL2 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ADAMTSL3 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 28/427 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADCY1 | c.1001A>G p.K334R | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.007); called by muse, mutect2
- ADGRE1 | c.805A>C p.I269L | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ADGRE5 | c.844G>A p.V282I (on ENST00000242786 / NM_078481.4; = p.V189I on NM_001784.5) | Missense Mutation (SNP) | VAF 30/361 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.41); called by muse, mutect2
- ADGRF3 | c.2503G>A p.G835R (on ENST00000311519 / NM_001145168.1; = p.G636R on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/480 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ADGRG4 | c.2011A>T p.T671S | Missense Mutation (SNP) | VAF 67/511 reads (13%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ADGRG4 | c.4651C>T p.P1551S | Missense Mutation (SNP) | VAF 60/504 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRL2 | c.4240G>A p.G1414R (on ENST00000370717 / NM_001366005.1; = p.G1358R on NM_012302.4) | Missense Mutation (SNP) | VAF 40/358 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AFF1 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 44/504 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- AHNAK | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 59/413 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AKAP3 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- AL358113.1 | c.3928C>T p.Q1310* | Nonsense Mutation (SNP) | VAF 35/333 reads (11%) | called by muse, mutect2, varscan2
- ALG2 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALPI | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.142); called by muse, mutect2
- AMPH | c.1646C>T p.S549F | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK1 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ANKRD12 | c.5730G>T p.R1910S | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANKRD20A2P | c.2461A>C p.K821Q | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); called by muse, mutect2
- ANKRD50 | c.4129G>A p.G1377S | Missense Mutation (SNP) | VAF 46/367 reads (13%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ANO5 | c.1091G>A p.R364K | Missense Mutation (SNP) | VAF 31/338 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.078); called by muse, mutect2
- APOA5 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 45/516 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- APOA5 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 45/516 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- APOBR | c.3153T>A p.H1051Q (on ENST00000431282; = p.H1060Q on NM_018690.4) | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2
- ARHGAP26 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ARHGAP28 | c.1921G>A p.G641R (on ENST00000383472 / NM_001366230.1; = p.G482R on NM_001010000.3) | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARHGAP30 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 198/601 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ARHGAP32 | c.1471C>T p.P491S (on ENST00000310343 / NM_001378025.1; = p.P142S on NM_014715.4) | Missense Mutation (SNP) | VAF 23/340 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2
- ARMC4 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ARRB1 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 34/414 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- ASAH2 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 47/500 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASPSCR1 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 50/507 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ATG4A | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATP1A1 | c.1919C>T p.T640I | Missense Mutation (SNP) | VAF 47/435 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- B4GALNT3 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- BAHD1 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 61/570 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAIAP3 | c.3106G>A p.D1036N | Missense Mutation (SNP) | VAF 44/402 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCAP31 | c.92+1G>A p.X31_splice | Splice Site (SNP) | VAF 27/250 reads (11%) | called by muse, mutect2, varscan2
- BDP1 | c.4826C>T p.P1609L | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2
- BOD1L1 | c.2118T>G p.D706E | Missense Mutation (SNP) | VAF 44/410 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.365); called by muse, mutect2
- BSN | c.3115G>A p.D1039N | Missense Mutation (SNP) | VAF 62/521 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BSPRY | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 63/461 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD11 | c.2594G>A p.G865D (on ENST00000280758 / NM_001018072.2; = p.G402D on NM_001017523.2) | Missense Mutation (SNP) | VAF 30/343 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2
- BTBD7 | c.2804C>T p.T935I | Missense Mutation (SNP) | VAF 54/477 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTNL9 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 37/466 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2
- BUD13 | c.789A>C p.Q263H | Missense Mutation (SNP) | VAF 50/453 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf143 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 33/428 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.935); called by muse, mutect2
- C1orf127 | c.2230C>T p.Q744* | Nonsense Mutation (SNP) | VAF 56/542 reads (10%) | called by muse, mutect2
- C1orf21 | c.99_102delinsTAA p.E33Dfs*13 | Frame Shift Del (DEL) | VAF 68/446 reads (15%) | called by pindel, varscan2*
- C2CD4C | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 78/562 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C5 | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- C6 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C6orf132 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); called by muse, varscan2
- C8A | c.688T>C p.Y230H | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CACNA2D1 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.444); called by muse, mutect2
- CACNA2D4 | c.876A>G p.I292M | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.882); called by muse, mutect2
- CAPN10 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CAPN7 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.164); called by muse, mutect2
- CARS1 | c.1247C>T p.T416I | Missense Mutation (SNP) | VAF 25/427 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CBFA2T2 | c.357G>T p.L119F | Missense Mutation (SNP) | VAF 34/487 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- CBFA2T3 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 50/539 reads (9%) | called by muse, mutect2
- CCDC136 | c.3250G>A p.D1084N | Missense Mutation (SNP) | VAF 42/364 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CCDC168 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 33/369 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- CCDC57 | c.2069C>T p.A690V | Missense Mutation (SNP) | VAF 46/434 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CCDC61 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 40/462 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC65 | c.1182G>A p.V394= | Splice Region (SNP) | VAF 23/207 reads (11%) | called by muse, mutect2, varscan2
- CCDC73 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC88C | c.5066C>T p.P1689L | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.057); called by muse, mutect2
- CCDC9B | c.1298G>A p.R433K | Missense Mutation (SNP) | VAF 65/739 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- CCN4 | c.319C>G p.R107G | Missense Mutation (SNP) | VAF 47/397 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCNH | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CD1D | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 74/764 reads (10%) | called by muse, mutect2
- CD200 | c.473G>A p.G158E (on ENST00000473539 / NM_001004196.3; = p.G133E on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2
- CD300LG | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 49/427 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD8B | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 64/447 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- CDC20 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 61/583 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CDH20 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 60/512 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CDH3 | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 40/463 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2
- CELA1 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CENPJ | c.3230G>C p.R1077P | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CFAP20DC | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 22/283 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.887); called by muse, mutect2
- CFAP54 | c.8591C>T p.S2864F | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- CFAP69 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CHCHD4 | c.27G>T p.K9N (on ENST00000396914 / NM_001098502.2; = p.K22N on NM_144636.3) | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHRDL2 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 42/536 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- CHRNA10 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 66/626 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- CHRNA10 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 66/626 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2
- CHRNA7 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 42/1092 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.05); called by muse, mutect2
- CHRNB1 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 36/490 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.129); called by muse, mutect2
- CLDN2 | c.503T>A p.I168N | Missense Mutation (SNP) | VAF 54/511 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CLDN6 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 53/530 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.733); called by muse, mutect2
- CNTN5 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 34/724 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); called by muse, mutect2
- CNTNAP5 | c.3656C>T p.P1219L | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, varscan2
- COBL | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 46/565 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- COG7 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL28A1 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- COL4A1 | c.4270C>T p.P1424S | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.848); called by muse, mutect2
- COL4A2 | c.4136C>T p.P1379L | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- COL5A1 | c.2242G>A p.G748R | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2
- COL5A2 | c.2085+1G>A p.X695_splice | Splice Site (SNP) | VAF 31/250 reads (12%) | called by muse, mutect2, varscan2
- COL5A2 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 37/435 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); called by muse, mutect2
- COL6A2 | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 36/405 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL7A1 | c.8246G>A p.G2749E | Missense Mutation (SNP) | VAF 36/433 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL7A1 | c.1771G>T p.V591F | Missense Mutation (SNP) | VAF 43/390 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- COX6C | c.221T>G p.V74G | Missense Mutation (SNP) | VAF 80/277 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- CPNE2 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2
- CPXCR1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 73/438 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- CRABP2 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 170/540 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CRACD | c.2063G>A p.R688K | Missense Mutation (SNP) | VAF 43/410 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CROCC2 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 61/510 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- CROCC2 | c.2084G>C p.R695P | Missense Mutation (SNP) | VAF 65/568 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- CRP | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CSN1S1 | c.381T>G p.N127K | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2
- CSN2 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 34/428 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.063); called by muse, mutect2
- CTAGE1 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CTAGE15 | c.1161G>A p.M387I | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CWF19L1 | c.1584C>G p.D528E | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- CYP46A1 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 39/414 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYSLTR2 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAG1 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 45/591 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2
- DBX1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 53/486 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- DCAF1 | c.4370C>T p.S1457F | Missense Mutation (SNP) | VAF 44/478 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- DCC | c.148G>T p.V50F | Missense Mutation (SNP) | VAF 32/432 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2
- DCHS1 | c.2892del p.H964Qfs*97 | Frame Shift Del (DEL) | VAF 64/605 reads (11%) | called by mutect2, pindel*
- DDX20 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DDX51 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 49/313 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX53 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 50/536 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.133); called by muse, mutect2
- DDX60 | c.1449T>G p.D483E | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- DENND4A | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DGKZ | c.3170T>A p.L1057Q (on ENST00000454345 / NM_001105540.2; = p.L869Q on NM_003646.4) | Missense Mutation (SNP) | VAF 55/509 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DHX34 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 58/418 reads (14%) | called by muse, mutect2, varscan2
- DIP2C | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 59/394 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- DLGAP4 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 58/647 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- DMRTB1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 42/510 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.381); called by muse, mutect2
- DNA2 | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DNAH3 | c.12308G>A p.W4103* | Nonsense Mutation (SNP) | VAF 43/406 reads (11%) | called by muse, mutect2, varscan2
1,238 further variants in this file (474 protein-altering or splice-affecting, 692 silent, 72 other) are not listed here.
